Surgical pathology report (de-identified scan), TCGA case TCGA-61-1725, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1725-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -

- A. HIGH-GRADE SEROUS CARCINOMA.
- B. LYMPHOVASCULAR INVASION IS IDENTIFIED.

PART 2: ADNEXA, LEFT, SALPINGO-OOPHORECTOMY -

- A. HIGH-GRADE SEROUS CARCINOMA OF THE OVARY (9 CM).
- B. LYMPHOVASCULAR INVASION IS IDENTIFIED.
- C. SURFACE INVOLVED BY TUMOR.
- D. ENDOMETRIOSIS.
- E. FALLOPIAN TUBE WITH SEROUS CARCINOMA, INVOLVING FIMBRIATED END AND FALLOPIAN TUBE LUMEN.

PART 3: ADNEXA, RIGHT, SALPINGO-OOPHORECTOMY -

- A. HIGH-GRADE SEROUS CARCINOMA OF OVARY (11 CM) (see comment).
- B. LYMPHOVASCULAR INVASION IS IDENTIFIED.
- C. SURFACE INVOLVEMENT IS PRESENT.
- D. FALLOPIAN TUBE WITH SEROUS CARCINOMA CLUSTERS IN THE LUMEN.
- E. ENDOMETRIOSIS.
- F. PATHOLOGIC STAGE (see comment).

PART 4: UTERUS, CERVIX AND CUL-DE-SAC TUMOR, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (TUMOR DEBULKING) -

- A. HIGH-GRADE SEROUS CARCINOMA INVOLVING UTERINE SEROSA AND POSTERIOR CERVICAL SOFT TISSUE (CUL-DE-SAC REGION).
- B. ENDOMETRIAL POLYP.
- C. CERVICAL MUCOSA, HISTOLOGICALLY UNREMARKABLE.

PART 5: APPENDIX, APPENDECTOMY -

- A. HIGH-GRADE SEROUS CARCINOMA INVOLVING MESOAPPENDIX.
- B. APPENDIX, OBLITERATED.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 11 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus
ASSOCIATED OTHER LESION:	Endometriosis
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file d3eea5d0-4ff5-4ea3-a705-ca3149fc1d31 (TCGA-61-1725.8BCF7F73-ABE7-43D0-A7DA-EDE3F5C2BB04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).